Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4G9, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4G9-01A (Primary Tumor).

[page 1 of 4]
F

GROSS:

Specimen submitted: Distal gastrectomy, fresh
Measurement: Greater curvature 22.0 cm
Lesser curvature 12.0 cm
Proximal resection margin 13.0 cm
Distal resection margin 6.0 cm
Duodenum 0.8 cm

Lesions:

[1] Mass A

Tumor location:

Stomach: Lower body, posterior wall
From proximal resection margin - 5.5 cm
From distal resection margin - 4.0 cm

Tumor size: 5.0 x 2.0 x 1.6 cm

Tumor type: EGC I

[2] Mass B

Tumor location:

Stomach: Midbody, lesser curvature (0.9 cm away from the mass A)
From proximal resection margin - 4.0 cm
From distal resection margin - 5.5 cm

Tumor size: 2.0 x 1.0 x 0.2 cm

Tumor type: EGC IIa

Gross serosal invasion: No

Representative sections are submitted.

Gross photo: Present

Blocks

T1-3, polypoid mass (mass A) and surrounding tissue x 3

T4-5, slightly elevated mas (mass B) and surronding tissue x 2

(mucosa between two masses: green inked)

A, antral mucosa x 1

B, body mucosa x 1

P, proximal resection margin x 1

D, distal resection margin x 1

LN1-2, superior gastric lymph nodes x 2

LN3-4, inferior gastric lymph nodes x 2

1CD-0-3

adenocarcinoma, tubular 8211/3

Site: stomach, body C16.2

for
9/27/12

- over -

IRHAA Discrepancy		X
Case is (cited)		X

[page 2 of 4]
F

LN5, '1' lymph nodes x 1
LN6, '4sb' lymph nodes x 1
LN7, '5' lymph nodes x 1
LN8, '6' lymph nodes x 1
LN9, '7' lymph nodes x 1
LN10, '8' lymph nodes x 1
LN11, '9' lymph nodes x 1
LN12, '11p' lymph nodes x 1
LN13, '12' lymph nodes x 1

MICROSCOPIC:

[1] Mass A

Tumor type: Adenocarcinoma, moderately differentiated, arising in high-grade adenoma

Tumor size:

- Adenoma component: 5.0 x 2.0 x 1.6 cm
- Carcinoma component: 1.7 x 0.9 x 0.7 cm

Depth of tumor invasion:

T1: T1a-Muscularis mucosa (M)

[2] Mass B

Tumor type: Adenocarcinoma, well differentiated, microscopic, multifocal, arising in high-grade adenoma

Depth of tumor invasion:

T1: T1a-Mucosa and lamina propria

Margins: Proximal resection margin (-)
Distal resection margin (-)

Lauren classification: Intestinal

Ming classification (Growth pattern): Infiltrative

Lymphoid reaction: Present

Lymphovascular invasion: Absent

Venous (large vessel) invasion: Absent

Perineural invasion: Absent

Lymph node metastases:

NO: No regional lymph node metastasis

number of involved nodes (0) total number of nodes (42)

Distant metastasis(M):

MX: Distant metastasis cannot be assessed

Pathologic stage: pT1aNOMx

- over -

[page 3 of 4]
F

SPECIAL STAIN: Cresyl Violet stain reveals mild H. pylori.

NOT reported. Gross. .

Stomach, antrum, scopic, adenocarcinoma
Stomach, antrum, scopic, tubular adenoma, high grade, dysplasia
Stomach, angle, scopic, tubular adenoma, low grade, dysplasia

Large intestine, transverse colon, sigmoid colon, excisional biopsy, Tubular adenoma, low grade, dysplasia

DIAGNOSIS:

Stomach, distal gastrectomy:

- Adenocarcinoma, moderately differentiated, arising in high grade adenoma (early gastric cancer)
- Adenocarcinoma, well differentiated, microscopic, multifocal, arising in high grade adenoma (early gastric cancer)

Lymph node, perigastric, distal gastrectomy:

Superior gastric: No tumor present (0/5)
Inferior gastric: No tumor present (0/2)

Lymph node, regional, biopsy:

Labeled '1': No tumor present (0/4)
Labeled '4sb': Fibrofatty tissue
Labeled '5': Fibrofatty tissue
Labeled '6': No tumor present (0/3)
Labeled '7': No tumor present (0/7)
Labeled '8': No tumor present (0/6)
Labeled '9': No tumor present (0/3)
Labeled '11p': No tumor present (0/4)
Labeled '12': No tumor present (0/8)

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By (

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Intestinal Adenocarcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Intestinal Adenocarcinoma, Tubular Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	In addendum, we clarified that this is an intestinal adenocarcinoma, tubular type	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file dad080d0-d19e-47a5-9b13-238c65b9e060 (TCGA-HU-A4G9.90EBA539-31BA-47D7-8AFA-18F2F97C2119.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).